Somatic mutation profile of tumor specimen TCGA-FV-A4ZP-01A (aliquot TCGA-FV-A4ZP-01A-12D-A25V-10) from TCGA case TCGA-FV-A4ZP, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 78.8 years (28,771 days).
Specimen TCGA-FV-A4ZP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7efabf7-9d86-4ac2-9e0d-f60bf33fb0e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FV-A4ZP-11A (Solid Tissue Normal), aliquot TCGA-FV-A4ZP-11A-12D-A25V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6d74a886-b974-497d-8166-5aa5a1c27630

The open-access MAF lists 94 somatic variants for this specimen: 70 protein-altering or splice-affecting, 21 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 21, Frame Shift Del 4, Nonsense Mutation 3, Splice Site 2, 5'Flank 1, Intron 1, Translation Start Site 1, 3'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 60/98 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs786201059, CM076567, CM1212545, COSV52664318, COSV52687201, COSV52688214; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCB4 | c.2246A>T p.Q749L | Missense Mutation (SNP) | VAF 72/502 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.143); catalogued as COSV55938954; called by muse, mutect2, varscan2
- ADGRL1 | c.547C>T p.R183C (on ENST00000340736 / NM_001008701.3; = p.R178C on NM_014921.5) | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369670781; called by muse, mutect2, varscan2
- ADGRL3 | c.1394G>T p.R465I (on ENST00000506720 / NM_001322402.2; = p.R397I on NM_015236.6) | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.265); catalogued as COSV72268049, COSV72269923; called by muse, mutect2, varscan2
- ARHGEF6 | c.22G>A p.V8M | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV51693981; called by muse, mutect2, varscan2
- ARID3A | c.423G>C p.E141D | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0); catalogued as COSV55045512; called by muse, varscan2
- ARID5B | c.2361C>A p.S787R | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.133); catalogued as COSV54426164; called by muse, mutect2, varscan2
- BEND3 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 69/140 reads (49%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.946); catalogued as COSV64681760; called by muse, mutect2, varscan2
- BRCA2 | c.5987C>G p.A1996G | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs80358834, COSV66458686; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CAND2 | c.2852G>T p.G951V (on ENST00000456430 / NM_001162499.2; = p.G858V on NM_012298.3) | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1186910356, COSV55992390; called by muse, mutect2, varscan2
- CCDC190 | c.658G>T p.G220W | Missense Mutation (SNP) | VAF 28/252 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV63363276; called by muse, mutect2
- CELSR1 | c.7583C>T p.P2528L | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as rs533045376, COSV53095438; called by muse, mutect2, varscan2
- CEMIP2 | c.1150T>C p.Y384H | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV65488496; called by muse, mutect2, varscan2
- CHUK | c.2065G>A p.E689K | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT tolerated (0.92); PolyPhen benign (0.011); catalogued as COSV100956913, COSV64918424; called by muse, mutect2, varscan2
- CLPTM1 | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.288); catalogued as COSV61612572; called by muse, mutect2, varscan2
- CLTC | c.2669C>T p.P890L | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555606635, CM162958, COSV52250313; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- CRACD | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); catalogued as rs1336240262, COSV51727148; called by muse, mutect2, varscan2
- CRBN | c.38A>G p.N13S | Missense Mutation (SNP) | VAF 53/146 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.037); catalogued as COSV51641939; called by muse, varscan2
- CRNN | c.1366G>C p.D456H | Missense Mutation (SNP) | VAF 33/313 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV55123021, COSV55123485; called by muse, mutect2, varscan2
- DCHS1 | c.4949A>G p.Q1650R | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.028); catalogued as COSV55039625; called by muse, mutect2, varscan2
- DHX9 | c.3256G>A p.D1086N | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.084); catalogued as COSV62360989; called by muse, mutect2, varscan2
- FN1 | c.4376C>A p.A1459E | Missense Mutation (SNP) | VAF 39/315 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0.161); catalogued as COSV60559037; called by muse, mutect2, varscan2
- GALNT12 | c.1580A>G p.E527G | Missense Mutation (SNP) | VAF 41/238 reads (17%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.626); catalogued as COSV66663288; called by muse, mutect2, varscan2
- GLYATL1 | c.205G>A p.D69N (on ENST00000317391 / NM_001354699.1; = p.D100N on NM_080661.4) | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.061); catalogued as COSV55610296; called by muse, mutect2, varscan2
- GPRC6A | c.2128A>G p.T710A | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.49); PolyPhen benign (0.186); catalogued as COSV59954810; called by muse, mutect2, varscan2
- HPSE | c.1451G>A p.G484E | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.52); catalogued as COSV60987935; called by muse, mutect2, varscan2
- KLRK1 | c.382A>G p.M128V | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV53699357; called by muse, mutect2, varscan2
- LMO7 | c.1388C>A p.T463N (on ENST00000357063; = p.T193N on NM_015842.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV58542867; called by muse, mutect2, varscan2
- LRIT1 | c.102G>T p.M34I | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV63894801; called by muse, mutect2, varscan2
- MAN2C1 | c.1612C>T p.R538W | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.041); catalogued as rs377316574; called by muse, varscan2
- MAP2 | c.4982G>A p.R1661Q | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.947); catalogued as rs1487230722, COSV52300593; called by muse, mutect2, varscan2
- MAP4K2 | c.779_781del p.K260del | In Frame Del (DEL) | VAF 4/29 reads (14%) | catalogued as rs771074867; called by pindel, varscan2
- MMP2 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV54602507; called by muse, mutect2
- MON2 | c.1405G>T p.E469* | Nonsense Mutation (SNP) | VAF 18/117 reads (15%) | catalogued as COSV54803406; called by muse, mutect2, varscan2
- MRPL32 | c.313A>G p.N105D | Missense Mutation (SNP) | VAF 61/230 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV56239811; called by muse, mutect2, varscan2
- MYH15 | c.4561A>C p.I1521L | Missense Mutation (SNP) | VAF 23/101 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.253); catalogued as COSV56315625; called by muse, mutect2, varscan2
- MYOM1 | c.4484A>T p.N1495I | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.58); catalogued as COSV55297014; called by muse, mutect2, varscan2
- OCA2 | c.1269G>A p.W423* | Nonsense Mutation (SNP) | VAF 54/116 reads (47%) | catalogued as rs1397133196, COSV62352619; called by muse, mutect2, varscan2
- OR2H2 | c.799G>C p.E267Q | Missense Mutation (SNP) | VAF 10/419 reads (2%) | SIFT deleterious (0.01); PolyPhen benign (0.405); catalogued as COSV100590142; called by muse, mutect2
- OR51G1 | c.323C>A p.T108N | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.843); catalogued as COSV58969979; called by muse, mutect2, varscan2
- OTUD5 | c.8T>C p.I3T | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV50237920; called by muse, mutect2, varscan2
- PCDH17 | c.52C>A p.L18I | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV64976815; called by muse, mutect2, varscan2
- PTPRT | c.1611C>G p.S537R | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.232); catalogued as COSV61977689, COSV62024852; called by muse, mutect2, varscan2
- ROR1 | c.1372G>T p.A458S | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV64290592; called by muse, mutect2
- SACM1L | c.542A>T p.E181V | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV66614454; called by mutect2, varscan2
- SHLD1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs758092845, COSV57437519; called by muse, mutect2, varscan2
- SLC35F2 | c.1054A>G p.S352G | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.122); catalogued as COSV56184505; called by muse, mutect2, varscan2
- SPAG17 | c.1475G>T p.C492F | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); catalogued as COSV60463915, COSV60464681; called by muse, mutect2, varscan2
- STRADA | c.134C>T p.A45V (on ENST00000336174 / NM_001363786.1; = p.A8V on NM_153335.6) | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.08); catalogued as rs777619656, COSV55562895; called by muse, mutect2, varscan2
- TACR3 | c.1086-1G>C p.X362_splice | Splice Site (SNP) | VAF 13/74 reads (18%) | catalogued as COSV100511103, COSV59205571; called by muse, mutect2, varscan2
- TARS2 | c.275C>G p.A92G | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV64696383; called by muse, mutect2, varscan2
- TEAD1 | c.1192G>A p.E398K | Missense Mutation (SNP) | VAF 20/135 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57562145, COSV57568237; called by muse, mutect2, varscan2
- THEMIS | c.736C>A p.P246T | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.489); catalogued as COSV100965627, COSV64070330; called by muse, mutect2, varscan2
- TLR4 | c.1345C>T p.L449F (on ENST00000355622 / NM_138554.5; = p.L409F on NM_003266.4) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62923838; called by muse, mutect2, varscan2
- TOX | c.713G>A p.R238Q | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as rs1563366418, COSV63848814; called by muse, mutect2
- TXNDC2 | c.658A>T p.K220* (on ENST00000306084 / NM_001098529.2; = p.K153* on NM_032243.6) | Nonsense Mutation (SNP) | VAF 6/138 reads (4%) | catalogued as COSV60154559; called by muse, mutect2
- UBAC2 | c.808G>A p.G270R (on ENST00000403766 / NM_001144072.2; = p.G235R on NM_177967.4) | Missense Mutation (SNP) | VAF 42/129 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.223); catalogued as COSV63119948; called by muse, mutect2, varscan2
- USH2A | c.6388A>G p.N2130D | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.824); catalogued as COSV56405224; called by muse, mutect2, varscan2
- USH2A | c.3706G>C p.V1236L | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.123); catalogued as COSV56405237; called by muse, mutect2, varscan2
- VN1R4 | c.317T>G p.V106G | Missense Mutation (SNP) | VAF 38/302 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.281); catalogued as COSV60805348; called by muse, mutect2, varscan2
- ZBTB43 | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as COSV65095096; called by mutect2, varscan2
- ZNF214 | c.1304T>A p.V435E | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV53482993; called by muse, mutect2, varscan2
- ZNF43 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.785); catalogued as COSV61684986; called by muse, varscan2
- ZNF791 | c.1001G>A p.G334E | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.913); catalogued as COSV58482029; called by muse, mutect2, varscan2
- AGFG1 | c.541-9_550del p.X181_splice | Splice Site (DEL) | VAF 18/114 reads (16%) | called by mutect2, pindel
- CACNA1E | c.4093del p.L1365Sfs*18 | Frame Shift Del (DEL) | VAF 52/161 reads (32%) | called by mutect2, pindel, varscan2
- KIF16B | c.1407_1411del p.L470Sfs*11 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- METTL21C | c.294del p.L98Ffs*12 | Frame Shift Del (DEL) | VAF 9/61 reads (15%) | called by mutect2, pindel, varscan2
- TMEM236 | c.370G>T p.D124Y | Missense Mutation (SNP) | VAF 182/568 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.748); called by muse, mutect2, varscan2
- TRAM1L1 | c.761_777del p.A254Gfs*2 | Frame Shift Del (DEL) | VAF 19/64 reads (30%) | called by mutect2, pindel, varscan2
- ANKRD30A | c.1719G>A p.E573= (on ENST00000611781; = p.E517= on NM_052997.2) | Silent (SNP) | VAF 62/849 reads (7%) | catalogued as rs1564495774, COSV64616116; called by muse, mutect2
- CRACD | c.1761G>A p.S587= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as COSV51727160; called by muse, mutect2, varscan2
- DEDD | c.927G>C p.L309= | Silent (SNP) | VAF 66/198 reads (33%) | catalogued as rs1187099077, COSV63502380; called by muse, mutect2, varscan2
- FHDC1 | c.171C>T p.S57= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV99471743; called by muse, mutect2, varscan2
- GREB1 | c.3108G>A p.G1036= | Silent (SNP) | VAF 35/163 reads (21%) | catalogued as COSV52192316; called by muse, mutect2, varscan2
- KLHL32 | c.594C>A p.R198= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100987513; called by mutect2, varscan2
- LHCGR | c.819G>A p.L273= | Silent (SNP) | VAF 6/61 reads (10%) | catalogued as COSV54300619; called by muse, mutect2, varscan2
- MUC16 | c.26889C>T p.S8963= | Silent (SNP) | VAF 61/291 reads (21%) | catalogued as COSV67480751; called by muse, mutect2, varscan2
- PCDHGA5 | c.2040C>A p.T680= | Silent (SNP) | VAF 38/178 reads (21%) | catalogued as COSV53993998; called by muse, mutect2, varscan2
- PI4KA | c.1908C>T p.P636= | Silent (SNP) | VAF 15/61 reads (25%) | catalogued as COSV55417582; called by muse, mutect2, varscan2
- PKP1 | c.1416G>A p.V472= | Silent (SNP) | VAF 17/107 reads (16%) | catalogued as rs376484047; called by muse, mutect2, varscan2
- POTEM | c.168A>T p.T56= | Silent (SNP) | VAF 54/401 reads (13%) | called by muse, varscan2
- PRRC2B | c.6195C>T p.A2065= | Silent (SNP) | VAF 12/104 reads (12%) | catalogued as COSV57645835; called by muse, mutect2, varscan2
- PTPRM | c.2190C>G p.V730= | Silent (SNP) | VAF 67/114 reads (59%) | catalogued as COSV59871877; called by muse, varscan2
- RALYL | c.837T>C p.D279= | Silent (SNP) | VAF 33/209 reads (16%) | catalogued as rs751319727, COSV72823549; called by muse, varscan2
- SCN8A | c.1824C>T p.R608= | Silent (SNP) | VAF 10/15 reads (67%) | catalogued as rs756753738, COSV61987948; called by muse, mutect2
- SLC14A1 | c.39C>A p.P13= | Silent (SNP) | VAF 12/163 reads (7%) | catalogued as COSV58933295; called by muse, mutect2
- THEMIS | c.735C>A p.L245= | Silent (SNP) | VAF 14/57 reads (25%) | catalogued as COSV100965629; called by muse, mutect2, varscan2
- TRH | c.453G>T p.R151= | Silent (SNP) | VAF 48/133 reads (36%) | catalogued as COSV57015418; called by muse, mutect2, varscan2
- ZBED1 | c.909C>T p.F303= | Silent (SNP) | VAF 5/106 reads (5%) | catalogued as COSV100586127; called by muse, mutect2
- ZNF280B | c.42G>A p.Q14= | Silent (SNP) | VAF 41/269 reads (15%) | catalogued as COSV64529390; called by muse, mutect2, varscan2
- CPLANE1 | c.*5057A>G | 3'UTR (SNP) | VAF 19/130 reads (15%) | catalogued as rs762263576, COSV57068086; called by muse, mutect2, varscan2
- DISC1 | c.1117+20523A>G | Intron (SNP) | VAF 11/123 reads (9%) | catalogued as COSV54413520; called by muse, mutect2
- LAMTOR5 | chr1:110407865 A>G | 5'Flank (SNP) | VAF 26/126 reads (21%) | catalogued as COSV56679277; called by muse, mutect2, varscan2
